Somatic mutation profile of tumor specimen C3L-01247-01 (aliquot CPT0080700009) from CPTAC case C3L-01247, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage III; FIGO stage: Stage III; Tumor grade: G3; Age at diagnosis: 63.5 years (23,181 days).
Specimen C3L-01247-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 53269d16-dc3e-4b6e-a16a-c4658002350d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01247-72 (Blood Derived Normal), aliquot CPT0080800002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/77b09053-1672-4ff5-8847-0542c43dab84

The open-access MAF lists 20 somatic variants for this specimen: 12 protein-altering or splice-affecting, 4 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 4, Intron 2, RNA 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.248T>C p.F83S | Missense Mutation (SNP) | VAF 10/123 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.06); catalogued as rs1560137208, COSV55924440, COSV55950009; ClinVar: pathogenic; called by muse, mutect2
- PPP2R1A | c.536C>G p.P179R | Missense Mutation (SNP) | VAF 11/189 reads (6%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs786205228, CM153573, COSV59042232, COSV59042841; ClinVar: likely pathogenic; called by muse, mutect2
- TP53 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 38/528 reads (7%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- DYSF | c.5792G>A p.R1931H | Missense Mutation (SNP) | VAF 24/523 reads (5%) | SIFT tolerated (0.8); PolyPhen benign (0.001); catalogued as rs1167021157, COSV50267163; called by muse, mutect2
- OLFM4 | c.893G>A p.R298K | Missense Mutation (SNP) | VAF 29/422 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.888); catalogued as rs1283352695, COSV54576266, COSV99524652; called by muse, mutect2
- PCDHGC3 | c.1387G>A p.D463N | Missense Mutation (SNP) | VAF 12/273 reads (4%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV52756952; called by muse, mutect2
- PLXNB2 | c.236C>A p.T79K | Missense Mutation (SNP) | VAF 20/222 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV63782186; called by muse, mutect2
- BMF | c.410T>C p.L137P | Missense Mutation (SNP) | VAF 18/204 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CORO2B | c.1016G>A p.R339H | Missense Mutation (SNP) | VAF 20/214 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PGM2 | c.792G>T p.Q264H | Missense Mutation (SNP) | VAF 16/211 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); called by muse, mutect2
- SF3A3 | c.94A>T p.T32S | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT tolerated (0.51); PolyPhen benign (0.113); called by muse, mutect2
- TOP2B | c.649A>G p.N217D (on ENST00000264331 / NM_001330700.2; = p.N212D on NM_001068.3) | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated (0.94); PolyPhen benign (0.005); called by muse, mutect2
- BHMG1 | c.1086G>T p.G362= | Silent (SNP) | VAF 19/320 reads (6%) | called by muse, mutect2
- JPH2 | c.705G>A p.S235= | Silent (SNP) | VAF 37/309 reads (12%) | catalogued as COSV100881801; called by muse, mutect2, varscan2
- MAGEB18 | c.495G>A p.K165= | Silent (SNP) | VAF 16/168 reads (10%) | called by muse, mutect2, varscan2
- NPAP1 | c.748C>A p.R250= | Silent (SNP) | VAF 12/126 reads (10%) | catalogued as rs200510789, COSV100274923, COSV61511489; called by muse, mutect2
- AC136628.2 | n.101T>C | RNA (SNP) | VAF 4/40 reads (10%) | catalogued as rs137998943; called by mutect2, varscan2
- CEACAM5 | c.-1C>T | 5'UTR (SNP) | VAF 20/212 reads (9%) | catalogued as rs782317994; called by muse, mutect2
- CHST13 | c.97+4862C>T | Intron (SNP) | VAF 18/262 reads (7%) | called by muse, mutect2
- SLC25A36 | c.385+3792T>G | Intron (SNP) | VAF 14/332 reads (4%) | called by muse, mutect2
